CCDI case PBBWZZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/d23a54e5-47c3-47b9-b78d-40cecaf7ac29

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 13.7 years (5,021 days).

Biospecimens (3 samples)
- Sample 0DJM8J: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJM8P: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJM98: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
